Gene-level copy-number profile of tumor specimen TCGA-W5-AA2Q-01A from TCGA case TCGA-W5-AA2Q, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 68.6 years (25,069 days).
Specimen TCGA-W5-AA2Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.4b148ff4-e661-497e-baee-afbc481350ed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-W5-AA2Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2cb550cc-067a-458f-9705-840e88799bfa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,368; copy number 2: 44,791; copy number 3: 6,402; copy number 4: 1,534; copy number 5: 93; copy number 6: 25; copy number 7: 1,399; copy number 8: 1,205.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-W5-AA2Q-01A-11D-A416-01): tumor purity 0.91, ploidy 2.29, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,722 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 7–8 (broad region; genes not listed).
- chr2:137,715,332–142,131,016, 38 genes, copy number 5–6 (within-gene range 3–6): Y_RNA, HNMT, LINC01832, RPL15P5, YWHAEP5, IDI1P1, RNF14P1, AC114763.1, AC114763.2, SPOPL, AC092620.1, AC092620.2, LINC02631, NXPH2, RN7SKP286, YY1P2, AHCYP4, AC023468.1, AC013265.1, AC062021.1, AC016710.1, SNORA72, MRPS18BP2, RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27, LRP1B, AC092156.1, MIR7157, COPRSP1, LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr2:192,774,082–192,776,073, 2 genes, copy number 5: RPS17P8, AC013401.2.
- chr10:59,955,430–67,696,195, 64 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:81,136,540–83,677,122, 10 genes, copy number 5: RPA2P2, AL096706.1, NRG3, AC010157.2, AC010157.1, NRG3-AS1, RNU6-441P, RNU6-478P, MARK2P15, LINC02650.
- chr16:70,802,084–71,230,722, 4 genes, copy number 5 (within-gene range 2–5): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.

Autosomal genes at a single copy (total copy number 1): 1,984. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
